TCGA case TCGA-A3-3335 — Kidney Renal Clear Cell Carcinoma (TCGA-KIRC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: International Genomics Consortium. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c04c5ac6-5b44-4e47-bf52-e4d92d76eea5

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 41 years; Vital status: Alive.

Diagnoses (2)
1. Clear cell adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8310/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 41.8 years (15,250 days); Year of diagnosis: 2006; AJCC pathologic T: T2a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Tumor grade: G4; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Clear cell adenocarcinoma, NOS). Age at diagnosis: 44.8 years (16,348 days); Days to diagnosis: 1,098 days (3.0 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 1,159 days (3.2 years); Treatment anatomic sites: Distant Site.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS; Surgery, NOS to Locoregional Site.

Follow-up (3 entries)
- Days to follow up: 665 days (1.8 years); Disease response: Tumor Free.
- Day 1,098 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 1,098 days (3.0 years).
- Days to follow up: 1,886 days (5.2 years); Disease response: Tumor Free.

Exposures
- Exposure type: Tobacco.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-A3-3335-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.1; Intermediate dimension: 0.9; Shortest dimension: 0.3.
  Slide TCGA-A3-3335-01A-01-BS1: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 5.
  Slide TCGA-A3-3335-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 5.
- Sample TCGA-A3-3335-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-A3-3335-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 2; Intermediate dimension: 0.8; Shortest dimension: 0.8.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Clear Cell Renal Carcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Lymph nodes examined: No.
- Follow-up form: Lost to follow-up: No; Treatment outcome at TCGA followup: Complete Remission/Response; Treatment outcome first course: Complete Remission/Response; New tumor event surgery: No; Tumor status: Tumor free; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No; New tumor event surgery met: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,886 days; disease-specific survival: no event (censored), 1,886 days; disease-free interval: event (new tumor event after initially disease-free), 1,098 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,098 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-A3-3335-01): tumor purity 0.63, ploidy 1.91, whole-genome doublings 0 (call status: legacy_call).
